Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A4XL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A4XL-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Skin per TSS - non-glabrous lw

Tumor size: 1.7 x 1.5 x 0.7 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Nodular melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: : 7.0 mm deep, IV level by Clarc

ICD-0-3

Melanoma, nodular 8721/3

Site: SKIN, NOS C44.9

lw
10/26/12

ICPAA Discrepancy		
Reviewed (Initials)	10/26/12	

Source: NCI Genomic Data Commons file de252e15-c0ae-4b17-9118-a875f534745e (TCGA-EB-A4XL.7578E846-075C-47C6-ABAC-C6F2F54D0199.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).